Somatic mutation profile of tumor specimen TCGA-CC-A3MB-01A (aliquot TCGA-CC-A3MB-01A-11D-A20W-10) from TCGA case TCGA-CC-A3MB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 36.3 years (13,255 days).
Specimen TCGA-CC-A3MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c67d956-45de-4ad0-94ae-86ea11c3ba5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A3MB-10A (Blood Derived Normal), aliquot TCGA-CC-A3MB-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e4ccc34-896f-4e2c-9286-10a522c1abf9

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 81/109 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.3724C>T p.R1242C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159018525, COSV55589458; called by muse, mutect2, varscan2
- AFF1 | c.3100T>A p.S1034T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV57119418; called by muse, mutect2, varscan2
- ATM | c.2600G>C p.S867T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53741372; called by muse, mutect2, varscan2
- BAG6 | c.2185C>T p.P729S (on ENST00000676571; = p.P682S on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV52990102, COSV99277746; called by muse, mutect2
- BCL11A | c.2387A>C p.N796T (on ENST00000335712 / NM_001365609.1; = p.N830T on NM_022893.4) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59629104; called by muse, mutect2, varscan2
- C5AR2 | c.680C>A p.A227E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as COSV57255948; called by muse, mutect2, varscan2
- CCDC8 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.4); catalogued as COSV56773152; called by muse, mutect2, varscan2
- CCZ1B | c.938A>T p.H313L | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV57437141; called by muse, mutect2, varscan2
- CDC7 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV52310449; called by muse, mutect2, varscan2
- CDCP1 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.602); catalogued as COSV56105055; called by muse, mutect2, varscan2
- CNOT2 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57502472; called by muse, mutect2, varscan2
- CNTNAP5 | c.548T>G p.F183C | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV70484195; called by muse, mutect2, varscan2
- COL15A1 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs201906975, COSV100897388; called by muse, mutect2, varscan2
- CYFIP2 | c.2197C>G p.Q733E (on ENST00000616178 / NM_001291722.2; = p.Q708E on NM_014376.4) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV59035974; called by muse, mutect2, varscan2
- DNAH17 | c.4536G>C p.Q1512H | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs1417358952, COSV67753528; called by muse, mutect2, varscan2
- DPP10 | c.2029A>C p.I677L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV59683392; called by muse, mutect2, varscan2
- EHD4 | c.413+1G>T p.X138_splice | Splice Site (SNP) | VAF 35/63 reads (56%) | catalogued as rs1323636708, COSV55004533; called by muse, mutect2, varscan2
- EPHX1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55300442; called by muse, mutect2, varscan2
- FAM81A | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.554); catalogued as COSV55677528; called by muse, mutect2, varscan2
- FMO1 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV61445562; called by muse, mutect2, varscan2
- GJA1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as COSV56997844; called by muse, mutect2, varscan2
- HKDC1 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63576480, COSV63576898; called by muse, mutect2, varscan2
- HMMR | c.1827T>G p.N609K | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV62374399; called by muse, mutect2
- ICA1 | c.688A>G p.M230V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1032440988, COSV99655218; called by muse, mutect2, varscan2
- ICA1 | c.687C>A p.H229Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1381548654, COSV99655222; called by muse, mutect2, varscan2
- KAT7 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 93/113 reads (82%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.022); catalogued as COSV52014244; called by muse, mutect2, varscan2
- KMT2E | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 23/143 reads (16%) | catalogued as COSV57572718; called by muse, mutect2, varscan2
- MACF1 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 137/175 reads (78%) | catalogued as COSV58363368, COSV58371152; called by muse, mutect2, varscan2
- MS4A14 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55734627; called by muse, mutect2, varscan2
- NBEA | c.4883C>A p.A1628D | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.981); catalogued as COSV59780517; called by muse, mutect2, varscan2
- OR10A7 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV58278291, COSV58279043; called by muse, mutect2, varscan2
- PAK3 | c.1164A>T p.Q388H (on ENST00000262836 / NM_001324328.2; = p.Q373H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV53273794; called by muse, mutect2, varscan2
- PPP2R2C | c.359T>A p.I120N | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58672252; called by muse, mutect2, varscan2
- PRKD2 | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as COSV52186474, COSV52188714; called by muse, mutect2, varscan2
- PTCHD1 | c.2271A>T p.L757F | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV65059948; called by muse, mutect2, varscan2
- RICTOR | c.2383T>A p.S795T | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57121335; called by muse, mutect2, varscan2
- RIPOR3 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV50388213; called by muse, mutect2, varscan2
- SETDB1 | c.2885C>G p.S962* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as COSV54981324; called by muse, mutect2
- SF1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.982); catalogued as rs766563165, COSV57113593; called by muse, mutect2, varscan2
- SGCD | c.272A>T p.K91I (on ENST00000435422 / NM_001128209.2; = p.K92I on NM_000337.5) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61907878; called by muse, mutect2, varscan2
- SLC24A4 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); catalogued as COSV54111905; called by muse, mutect2, varscan2
- SLCO6A1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65806016; called by muse, mutect2
- SPTBN2 | c.1866C>G p.S622R | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV59451411; called by muse, mutect2, varscan2
- TMEM132A | c.1528C>T p.R510C (on ENST00000453848 / NM_178031.3; = p.R511C on NM_017870.4) | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50005010; called by muse, mutect2, varscan2
- TTN | c.2692G>A p.V898M (on ENST00000591111; = p.V852M on NM_003319.4) | Missense Mutation (SNP) | VAF 12/255 reads (5%) | PolyPhen possibly damaging (0.584); catalogued as COSV60023696; called by muse, mutect2
- USH2A | c.3318T>C p.S1106= | Splice Region (SNP) | VAF 10/17 reads (59%) | catalogued as COSV56363175; called by muse, mutect2, varscan2
- USP34 | c.2429C>A p.A810E | Missense Mutation (SNP) | VAF 102/156 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as COSV68400809; called by muse, mutect2, varscan2
- WASHC2C | c.3410C>T p.S1137F (on ENST00000336378; = p.S1116F on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1462524493; called by muse, mutect2, varscan2
- WNT9B | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 71/129 reads (55%) | catalogued as COSV51518312; called by muse, mutect2, varscan2
- XIRP1 | c.4349T>C p.M1450T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61137472; called by muse, mutect2, varscan2
- ZBTB1 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV62437981; called by muse, mutect2, varscan2
- ZNF208 | c.2783G>T p.W928L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV68104586; called by muse, mutect2, varscan2
- ZNF749 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV61945985; called by muse, mutect2
- LATS1 | c.2546_2548del p.L849_C850delinsR | In Frame Del (DEL) | VAF 110/137 reads (80%) | called by mutect2, pindel, varscan2
- OPN4 | c.1014del p.I338Mfs*56 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel*, varscan2
- TRAK1 | c.825_864del p.E275Dfs*4 (on ENST00000327628 / NM_001349247.2; = p.E217Dfs*4 on NM_014965.5) | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel
- ANKIB1 | c.3090T>C p.S1030= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV56060966; called by muse, mutect2, varscan2
- ARAP3 | c.282C>T p.P94= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as rs146312944; called by muse, mutect2, varscan2
- BRINP2 | c.1170A>T p.L390= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs1398005981, COSV64177240; called by muse, mutect2, varscan2
- CCDC88C | c.3450C>T p.N1150= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs935425414, COSV66237607; called by muse, mutect2
- CDH9 | c.630G>T p.V210= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV50277125; called by muse, mutect2, varscan2
- CHRM3 | c.1467G>A p.A489= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs762495692, COSV55088007; called by muse, mutect2, varscan2
- EGR3 | c.870C>T p.D290= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV57833389; called by muse, varscan2
- GJA5 | c.831A>G p.G277= | Silent (SNP) | VAF 70/245 reads (29%) | catalogued as rs782480939, COSV54784012; called by muse, mutect2, varscan2
- KCNMA1 | c.3075A>G p.E1025= (on ENST00000286628 / NM_001161352.2; = p.E967= on NM_002247.4) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV54245103; called by muse, mutect2, varscan2
- KRI1 | c.651C>G p.S217= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV57264426; called by muse, mutect2, varscan2
- LGI4 | c.429G>A p.L143= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as rs191436645; called by muse, mutect2, varscan2
- LMNA | c.1905C>T p.G635= | Silent (SNP) | VAF 46/221 reads (21%) | catalogued as COSV61542813; called by muse, mutect2, varscan2
- SELENON | c.1302T>A p.T434= | Silent (SNP) | VAF 60/82 reads (73%) | catalogued as COSV62524640; called by muse, mutect2, varscan2
- SFMBT1 | c.1044T>G p.P348= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56253651; called by muse, mutect2, varscan2
- SLC46A2 | c.723C>T p.P241= | Silent (SNP) | VAF 47/64 reads (73%) | catalogued as rs577863419, COSV100953527, COSV65289956; called by muse, mutect2, varscan2
- TSPOAP1 | c.3120G>T p.L1040= | Silent (SNP) | VAF 78/106 reads (74%) | catalogued as COSV52107768; called by muse, mutect2, varscan2
- TYW3 | c.153C>T p.G51= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV61717638; called by muse, mutect2, varscan2
- UBOX5 | c.309C>T p.G103= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV53905818; called by muse, mutect2, varscan2
- UCP1 | c.393G>A p.G131= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV53767762; called by muse, mutect2, varscan2
- UROC1 | c.162G>A p.P54= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs557996880, COSV52032559, COSV52041752; called by muse, mutect2, varscan2
- ZFP1 | c.1011A>G p.S337= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60033185; called by muse, mutect2, varscan2
